Somatic mutation profile of tumor specimen C3N-01494-03 (aliquot CPT0106200006) from CPTAC case C3N-01494, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 64.3 years (23,476 days).
Specimen C3N-01494-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78cbe3fc-78c0-4926-8f4f-43e97d41c262.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01494-32 (Blood Derived Normal), aliquot CPT0110060002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd11941f-dd53-4617-b7af-76028099da43

The open-access MAF lists 408 somatic variants for this specimen: 281 protein-altering or splice-affecting, 110 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 246, Silent 110, Nonsense Mutation 18, Splice Region 9, Splice Site 6, Intron 6, 3'UTR 4, 5'Flank 3, RNA 2, 3'Flank 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/336 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- PIK3CA | c.3194A>T p.H1065L | Missense Mutation (SNP) | VAF 43/296 reads (15%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.84); catalogued as rs1560150596, COSV55930367; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RPS6KA4 | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 75/572 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as COSV53700569; called by muse, mutect2, varscan2
- ABCA12 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 32/258 reads (12%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs193145048, COSV55951779; called by muse, varscan2
- ABCC10 | c.2936C>T p.S979F (on ENST00000372530 / NM_001198934.2; = p.S951F on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/449 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV55093064; called by muse, mutect2, varscan2
- ADAM23 | c.2146C>T p.P716S | Missense Mutation (SNP) | VAF 73/494 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV52232561; called by muse, mutect2, varscan2
- ADAMTS8 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 44/439 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs748316308, COSV99961734; called by muse, mutect2, varscan2
- ADAMTS9 | c.3228G>T p.Q1076H | Missense Mutation (SNP) | VAF 41/266 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.225); catalogued as rs1487126472; called by muse, mutect2, varscan2
- AGTR1 | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 48/415 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100836960, COSV62558901; called by muse, mutect2, varscan2
- ANKRD30A | c.917C>T p.A306V (on ENST00000611781; = p.A250V on NM_052997.2) | Missense Mutation (SNP) | VAF 114/568 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV100654246; called by muse, mutect2, varscan2
- ARHGEF28 | c.4750C>T p.P1584S | Missense Mutation (SNP) | VAF 42/314 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1387549003; called by muse, mutect2, varscan2
- ATP13A2 | c.2557C>T p.R853C | Missense Mutation (SNP) | VAF 46/409 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772243999, COSV100454395; called by muse, mutect2, varscan2
- BDP1 | c.7472C>T p.S2491L | Missense Mutation (SNP) | VAF 47/356 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1337720585, COSV62429076; called by muse, mutect2, varscan2
- BMP10 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 61/374 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54894238, COSV99770474; called by muse, mutect2, varscan2
- BRD7 | c.1705C>T p.P569S | Missense Mutation (SNP) | VAF 59/422 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.061); catalogued as rs746738131; called by muse, mutect2, varscan2
- BRINP3 | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 28/279 reads (10%) | catalogued as COSV66514373; called by muse, mutect2, varscan2
- BRPF3 | c.1903G>A p.D635N | Missense Mutation (SNP) | VAF 52/352 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60209208; called by muse, mutect2, varscan2
- C1QTNF4 | c.902G>A p.G301D | Missense Mutation (SNP) | VAF 67/580 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); catalogued as rs1418830230; called by muse, mutect2, varscan2
- C1QTNF9B | c.580G>A p.G194S | Missense Mutation (SNP) | VAF 68/624 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.234); catalogued as rs1388943191, COSV65944341; called by muse, mutect2, varscan2
- CACNA1B | c.2491G>A p.G831R | Missense Mutation (SNP) | VAF 75/489 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.127); catalogued as rs891641720; called by muse, mutect2, varscan2
- CAMK2D | c.1369C>T p.R457C | Missense Mutation (SNP) | VAF 46/424 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs776889531; called by muse, mutect2, varscan2
- CAPN8 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 47/367 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs1262955686; called by muse, mutect2, varscan2
- CCDC43 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 48/443 reads (11%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs770767662; called by muse, mutect2, varscan2
- CCNA1 | c.781C>T p.R261* | Nonsense Mutation (SNP) | VAF 47/462 reads (10%) | catalogued as rs267603811, COSV55220556; called by muse, mutect2, varscan2
- CCNF | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 45/384 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.118); catalogued as COSV53542389; called by muse, mutect2, varscan2
- CDH8 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 62/377 reads (16%) | catalogued as rs267604590, COSV100182320, COSV54846997; called by muse, mutect2, varscan2
- CHD4 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 41/401 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as rs775541121, COSV58905412; called by muse, mutect2
- CMYA5 | c.9970C>T p.P3324S | Missense Mutation (SNP) | VAF 22/336 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.133); catalogued as rs371235407; called by muse, mutect2
- CNKSR2 | c.938G>A p.W313* | Nonsense Mutation (SNP) | VAF 29/268 reads (11%) | catalogued as COSV99667291; called by muse, mutect2, varscan2
- CNTN6 | c.1493-1G>A p.X498_splice | Splice Site (SNP) | VAF 34/214 reads (16%) | catalogued as CS1410395, COSV100610290; called by muse, mutect2, varscan2
- COL6A5 | c.5182G>A p.G1728R | Missense Mutation (SNP) | VAF 33/274 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55200132; called by muse, mutect2, varscan2
- CPNE8 | c.471G>A p.R157= | Splice Region (SNP) | VAF 17/226 reads (8%) | catalogued as COSV58843640; called by muse, mutect2
- CR2 | c.784G>A p.G262R | Missense Mutation (SNP) | VAF 50/372 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0.006); catalogued as COSV65509241; called by muse, mutect2, varscan2
- CR2 | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 60/404 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); catalogued as COSV65506536; called by muse, mutect2, varscan2
- CSMD3 | c.1801G>A p.D601N (on ENST00000297405 / NM_001363185.1; = p.D497N on NM_052900.3) | Missense Mutation (SNP) | VAF 44/392 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99852983; called by muse, mutect2, varscan2
- CTXN3 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 40/408 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751069265; called by muse, mutect2
- CWH43 | c.1450G>A p.G484R | Missense Mutation (SNP) | VAF 61/471 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773506919, COSV56944009; called by muse, mutect2, varscan2
- CYP2S1 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 73/567 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.127); catalogued as COSV59505226; called by muse, mutect2, varscan2
- DAB2 | c.170T>C p.I57T | Missense Mutation (SNP) | VAF 58/404 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as rs372468892; called by muse, mutect2, varscan2
- DHRS7C | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 39/272 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as rs1311966867; called by muse, mutect2, varscan2
- DIS3L | c.3064T>C p.Y1022H (on ENST00000319212 / NM_001143688.3; = p.Y939H on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 72/477 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1026276811; called by muse, mutect2, varscan2
- DNAH5 | c.10771G>A p.G3591R | Missense Mutation (SNP) | VAF 47/362 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54216434; called by muse, mutect2, varscan2
- DPYSL5 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 40/385 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as rs535536473; called by muse, mutect2, varscan2
- EXT2 | c.1564C>T p.R522C (on ENST00000343631; = p.R555C on NM_000401.3) | Missense Mutation (SNP) | VAF 57/418 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145507609; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FGG | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 26/270 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs200696007; called by muse, mutect2, varscan2
- FLOT1 | c.474+1G>A p.X158_splice | Splice Site (SNP) | VAF 53/382 reads (14%) | catalogued as rs1464638697; called by muse, mutect2, varscan2
- FRY | c.3431A>G p.Y1144C | Missense Mutation (SNP) | VAF 40/428 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV66575865; called by muse, mutect2
- FSIP2 | c.2516A>G p.Q839R | Missense Mutation (SNP) | VAF 45/311 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100554838; called by muse, mutect2, varscan2
- GALNT17 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 55/463 reads (12%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV61155523; called by muse, mutect2, varscan2
- GGT5 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 55/336 reads (16%) | SIFT tolerated (0.85); PolyPhen benign (0.031); catalogued as COSV54069924; called by muse, mutect2, varscan2
- GJA5 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 48/303 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.85); catalogued as COSV54785101; called by muse, mutect2, varscan2
- GNAS | c.1135G>A p.G379R | Missense Mutation (SNP) | VAF 71/567 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV58339029; called by muse, mutect2, varscan2
- GRIK4 | c.1732C>T p.P578S | Missense Mutation (SNP) | VAF 54/414 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs549334404; called by muse, mutect2, varscan2
- H1-1 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 37/402 reads (9%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.709); catalogued as rs773998686, COSV55119793; called by muse, mutect2
- HAPLN1 | c.232C>T p.R78* | Nonsense Mutation (SNP) | VAF 60/579 reads (10%) | catalogued as COSV57150052; called by muse, mutect2
- HMX2 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 91/571 reads (16%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs1234762969, COSV60592358; called by muse, mutect2, varscan2
- HTR3D | c.1228G>A p.E410K (on ENST00000382489 / NM_001163646.2; = p.E235K on NM_182537.3) | Missense Mutation (SNP) | VAF 69/562 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.673); catalogued as rs867525181, COSV61915730; called by muse, mutect2, varscan2
- IGDCC3 | c.2228C>T p.P743L | Missense Mutation (SNP) | VAF 69/422 reads (16%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1175564277; called by muse, mutect2, varscan2
- IGHM | c.752C>T p.T251I | Missense Mutation (SNP) | VAF 48/360 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as rs781860117; called by muse, mutect2, varscan2
- IGKV3-15 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 78/1180 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.296); catalogued as rs535673631; called by muse, mutect2
- ITGAX | c.1793G>A p.G598E | Missense Mutation (SNP) | VAF 43/423 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51652480; called by muse, mutect2, varscan2
- ITPR3 | c.2036C>T p.S679F | Missense Mutation (SNP) | VAF 43/314 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.17); catalogued as rs771821549, COSV100967907; called by muse, mutect2, varscan2
- KLKB1 | c.1490-1G>A p.X497_splice | Splice Site (SNP) | VAF 30/324 reads (9%) | catalogued as COSV99249592, COSV99250080; called by muse, mutect2
- LOXHD1 | c.3062G>A p.R1021Q | Missense Mutation (SNP) | VAF 29/193 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.096); catalogued as COSV56069718; called by muse, mutect2, varscan2
- LRP1B | c.10640G>A p.R3547K | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs868829441, COSV67249313; called by muse, mutect2
- LRTM1 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 38/227 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV55594301; called by muse, mutect2, varscan2
- METTL5 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 30/253 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.184); catalogued as rs1318319158; called by muse, mutect2, varscan2
- MFN2 | c.2170C>T p.L724F | Missense Mutation (SNP) | VAF 39/327 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52422482; called by muse, mutect2, varscan2
- MGAT4C | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 48/440 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749782221, COSV59833060; called by muse, mutect2, varscan2
- MYO3A | c.4617C>A p.F1539L | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.003); catalogued as COSV56341298; called by mutect2, varscan2
- NAGS | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 71/504 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.047); catalogued as rs1218242773; called by muse, mutect2, varscan2
- NALCN | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 29/264 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.288); catalogued as COSV51948786; called by muse, mutect2, varscan2
- NWD1 | c.2951G>A p.W984* | Nonsense Mutation (SNP) | VAF 30/226 reads (13%) | catalogued as rs1568383741; called by muse, mutect2, varscan2
- OR10G4 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 79/625 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.078); catalogued as rs773393333; called by muse, mutect2, varscan2
- OR2A25 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 44/419 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as rs1171718467, COSV68717068; called by muse, mutect2, varscan2
- OR4B1 | c.502G>A p.G168S | Missense Mutation (SNP) | VAF 40/368 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58884355; called by muse, mutect2, varscan2
- OR4C15 | c.557C>A p.S186Y (on ENST00000314644; = p.S132Y on NM_001001920.2) | Missense Mutation (SNP) | VAF 67/497 reads (13%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.476); catalogued as rs1204868838; called by muse, mutect2, varscan2
- OR4N2 | c.894G>A p.M298I | Missense Mutation (SNP) | VAF 20/229 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV100269985, COSV60050009; called by muse, mutect2, varscan2
- OR9A2 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 65/521 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1378488164; called by muse, mutect2, varscan2
- PCDH18 | c.2330C>T p.S777L | Missense Mutation (SNP) | VAF 48/448 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as rs770250677, COSV61266724; called by muse, mutect2, varscan2
- PCDH9 | c.1556G>A p.R519Q | Missense Mutation (SNP) | VAF 40/335 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.273); catalogued as rs768595393, COSV60526789; called by muse, mutect2, varscan2
- PCDHAC1 | c.1981C>T p.P661S | Missense Mutation (SNP) | VAF 73/462 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as COSV53858330; called by muse, mutect2, varscan2
- PDE1C | c.1211G>A p.R404K | Missense Mutation (SNP) | VAF 42/374 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV58518832; called by muse, mutect2, varscan2
- PTH2R | c.1567G>A p.D523N | Missense Mutation (SNP) | VAF 52/418 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.094); catalogued as COSV55920329; called by muse, mutect2, varscan2
- QSER1 | c.3295G>A p.G1099S (on ENST00000399302; = p.G1228S on NM_001076786.3) | Missense Mutation (SNP) | VAF 49/442 reads (11%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1380446909; called by muse, mutect2, varscan2
- RAB3B | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 45/353 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as rs764753734, COSV63228318; called by muse, mutect2, varscan2
- RBM43 | c.1039G>A p.G347R | Missense Mutation (SNP) | VAF 32/318 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV58878560; called by muse, mutect2, varscan2
- RBM44 | c.1207A>G p.T403A (on ENST00000611254; = p.T1037A on NM_001080504.2) | Missense Mutation (SNP) | VAF 22/252 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as rs1385504316; called by muse, mutect2
- RBM47 | c.1234C>T p.H412Y | Missense Mutation (SNP) | VAF 56/506 reads (11%) | SIFT tolerated, low confidence (0.39); PolyPhen possibly damaging (0.69); catalogued as COSV55935384; called by muse, mutect2, varscan2
- RHOG | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 59/453 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.371); catalogued as rs1378762902; called by muse, mutect2, varscan2
- RIMBP2 | c.1745C>T p.P582L | Missense Mutation (SNP) | VAF 74/438 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1257497524; called by muse, mutect2, varscan2
- RSC1A1 | c.1786C>T p.R596* | Nonsense Mutation (SNP) | VAF 57/392 reads (15%) | catalogued as rs1394473217, COSV100197553; called by muse, mutect2, varscan2
- RYR1 | c.11372C>T p.A3791V | Missense Mutation (SNP) | VAF 39/369 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100614083; called by muse, mutect2, varscan2
- RYR2 | c.4420G>A p.G1474R | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV63669854; called by muse, mutect2, varscan2
- SCAP | c.2266G>A p.D756N | Missense Mutation (SNP) | VAF 71/494 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.727); catalogued as rs755179051; called by muse, mutect2, varscan2
- SCN3A | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 39/381 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs775658357; called by muse, mutect2, varscan2
- SCNN1B | c.454C>T p.L152F | Missense Mutation (SNP) | VAF 70/577 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.025); catalogued as rs199832551; called by muse, mutect2, varscan2
- SENP5 | c.1624C>T p.P542S | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV60207500; called by muse, mutect2, varscan2
- SH2B2 | c.358G>A p.V120M | Missense Mutation (SNP) | VAF 68/512 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782144163; called by muse, mutect2, varscan2
- SH3RF3 | c.1999C>T p.P667S | Missense Mutation (SNP) | VAF 74/612 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.205); catalogued as rs367667693; called by muse, mutect2, varscan2
- SLC26A4 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.043); catalogued as CD138994, COSV55916736; called by muse, mutect2, varscan2
- SLC46A3 | c.920C>T p.S307F | Missense Mutation (SNP) | VAF 29/272 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.305); catalogued as rs1448703652, COSV57182190; called by muse, mutect2, varscan2
- SLC6A1 | c.1192-6C>T | Splice Region (SNP) | VAF 19/445 reads (4%) | catalogued as COSV55119872; called by muse, mutect2
- SLCO1B3 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 36/422 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.962); catalogued as rs368649517, COSV53948421; ClinVar: uncertain significance; called by muse, mutect2
- SPOCK3 | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 48/427 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.082); catalogued as rs866508166, COSV62715901; called by muse, mutect2, varscan2
- SPRED2 | c.541G>A p.G181S | Missense Mutation (SNP) | VAF 66/501 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs1374251131; called by muse, mutect2, varscan2
- STXBP5L | c.2770G>A p.E924K | Missense Mutation (SNP) | VAF 37/346 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.32); catalogued as COSV99876112; called by muse, mutect2, varscan2
- SYNE1 | c.533G>A p.G178E (on ENST00000367255 / NM_182961.4; = p.G185E on NM_033071.3) | Missense Mutation (SNP) | VAF 34/273 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868413668, COSV55053512; called by muse, mutect2, varscan2
- SYT5 | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 53/419 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1457391616, COSV62830419; called by muse, mutect2, varscan2
- TRIM67 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 68/536 reads (13%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.698); catalogued as COSV100792211; called by muse, mutect2, varscan2
- TRIOBP | c.5917G>A p.E1973K (on ENST00000644935 / NM_001039141.3; = p.E260K on NM_007032.5) | Missense Mutation (SNP) | VAF 75/596 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as rs1190598958; called by muse, mutect2, varscan2
- TSR3 | c.702C>T p.I234= | Splice Region (SNP) | VAF 52/397 reads (13%) | catalogued as rs367737359; called by muse, mutect2, varscan2
- TTN | c.41179G>A p.E13727K (on ENST00000591111; = p.E6303K on NM_003319.4) | Missense Mutation (SNP) | VAF 45/406 reads (11%) | PolyPhen probably damaging (0.994); catalogued as COSV60177633; called by muse, mutect2, varscan2
- USP29 | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 50/423 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.306); catalogued as COSV54146653; called by muse, varscan2
- USP29 | c.2572G>A p.D858N | Missense Mutation (SNP) | VAF 60/492 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756825168, COSV54140150, COSV54144117; called by muse, varscan2
- VIT | c.1984C>T p.P662S (on ENST00000389975 / NM_001177969.1; = p.P677S on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/406 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.422); catalogued as rs942045287; called by muse, mutect2, varscan2
- VPREB1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 46/356 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.038); catalogued as rs1207776261, COSV56426052; called by muse, mutect2, varscan2
- ZC3H3 | c.2621C>T p.S874F | Missense Mutation (SNP) | VAF 76/518 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.387); catalogued as rs1257549426; called by muse, varscan2
- ZNF229 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 43/349 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.023); catalogued as COSV52162508; called by muse, mutect2, varscan2
- ZNF527 | c.84G>A p.W28* | Nonsense Mutation (SNP) | VAF 27/425 reads (6%) | catalogued as COSV100648672; called by muse, mutect2
- ZNF638 | c.3863C>T p.P1288L | Missense Mutation (SNP) | VAF 35/310 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV52488918; called by muse, mutect2, varscan2
- ZNF662 | c.512G>A p.G171E | Missense Mutation (SNP) | VAF 38/296 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60240768; called by muse, mutect2, varscan2
- ZNF732 | c.1283G>A p.G428E | Missense Mutation (SNP) | VAF 45/403 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.155); catalogued as rs782175929; called by muse, mutect2, varscan2
- ZNF775 | c.391G>T p.G131W | Missense Mutation (SNP) | VAF 65/549 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61613851; called by muse, mutect2, varscan2
- ZNF827 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 54/448 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as rs780549116, COSV101061423; called by muse, mutect2, varscan2
- ZNF831 | c.3650G>A p.R1217Q | Missense Mutation (SNP) | VAF 40/588 reads (7%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs1162267747, COSV64042038; called by muse, mutect2
- ZNF831 | c.3970G>A p.A1324T | Missense Mutation (SNP) | VAF 53/482 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs373682660; called by muse, mutect2, varscan2
- ZNF84 | c.371G>A p.R124K | Missense Mutation (SNP) | VAF 38/324 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV59654125; called by muse, mutect2, varscan2
- AC233723.1 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 31/280 reads (11%) | PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- ADAMTS10 | c.29G>A p.W10* | Nonsense Mutation (SNP) | VAF 40/399 reads (10%) | called by muse, mutect2, varscan2
- ADAP2 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 49/399 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AHR | c.1331C>T p.S444F | Missense Mutation (SNP) | VAF 59/463 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- ANKRD30BL | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 16/177 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- AP5B1 | c.1897C>T p.P633S | Missense Mutation (SNP) | VAF 90/647 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APOB | c.3889G>A p.E1297K | Missense Mutation (SNP) | VAF 31/326 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- ARHGEF10L | c.1728C>T p.F576= | Splice Region (SNP) | VAF 26/248 reads (10%) | called by muse, mutect2, varscan2
- ASXL1 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 57/512 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ATP6V1D | c.94C>T p.L32F | Missense Mutation (SNP) | VAF 47/362 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AUTS2 | c.3295G>A p.D1099N | Missense Mutation (SNP) | VAF 52/467 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BEST1 | c.1438C>T p.P480S | Missense Mutation (SNP) | VAF 66/512 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- BPIFC | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 39/400 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2
- C11orf49 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 55/416 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- CACNA1A | c.1010G>A p.W337* | Nonsense Mutation (SNP) | VAF 31/333 reads (9%) | called by muse, mutect2
- CCDC174 | c.932G>A p.G311E | Missense Mutation (SNP) | VAF 23/308 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.984); called by muse, mutect2
- CCDC43 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 46/446 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD300H | c.173G>A p.R58K | Missense Mutation (SNP) | VAF 38/298 reads (13%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CDC27 | c.1823G>A p.G608E | Missense Mutation (SNP) | VAF 57/434 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEACAM5 | c.1343C>T p.S448F | Missense Mutation (SNP) | VAF 71/484 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- CFAP57 | c.1125G>A p.G375= | Splice Region (SNP) | VAF 33/254 reads (13%) | called by muse, mutect2, varscan2
- CGN | c.1949G>T p.S650I | Missense Mutation (SNP) | VAF 74/520 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- CHD4 | c.4825G>C p.E1609Q (on ENST00000357008 / NM_001363606.2; = p.E1622Q on NM_001273.5) | Missense Mutation (SNP) | VAF 78/562 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- CMYA5 | c.5338G>A p.A1780T | Missense Mutation (SNP) | VAF 66/500 reads (13%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CMYA5 | c.6598G>C p.E2200Q | Missense Mutation (SNP) | VAF 66/433 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- CNGA3 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 63/451 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- CPNE3 | c.449T>G p.L150R | Missense Mutation (SNP) | VAF 42/301 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYHR1 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 55/329 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DACT3 | c.334G>C p.G112R | Missense Mutation (SNP) | VAF 34/384 reads (9%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.964); called by muse, mutect2
- DCDC1 | c.1983G>A p.K661= | Splice Region (SNP) | VAF 18/283 reads (6%) | called by muse, mutect2
- DEFB113 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 34/284 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.144); called by muse, varscan2
- DENND2A | c.89A>G p.N30S | Missense Mutation (SNP) | VAF 67/547 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAH17 | c.8467T>C p.F2823L | Missense Mutation (SNP) | VAF 52/354 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DPYSL2 | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 64/377 reads (17%) | called by muse, mutect2, varscan2
- DSE | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 31/338 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DYNC1I2 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 44/271 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- ELF1 | c.995C>T p.S332F | Missense Mutation (SNP) | VAF 51/351 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ELOVL7 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 31/309 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- ERFL | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 52/352 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ETV7 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 67/369 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM189A1 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 57/432 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- FAM217A | c.18+1G>A p.X6_splice | Splice Site (SNP) | VAF 55/347 reads (16%) | called by muse, mutect2, varscan2
- FAT3 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 42/347 reads (12%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- FLT3 | c.2142G>A p.W714* | Nonsense Mutation (SNP) | VAF 46/319 reads (14%) | called by muse, mutect2, varscan2
- FMN1 | c.1280G>A p.S427N | Missense Mutation (SNP) | VAF 72/503 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- FMN2 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 68/730 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.103); called by muse, mutect2
- FOXK1 | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 70/800 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.416); called by muse, mutect2
- FRAS1 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 35/336 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- GABBR1 | c.2807G>A p.G936E | Missense Mutation (SNP) | VAF 78/783 reads (10%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- GAK | c.914C>T p.S305F | Missense Mutation (SNP) | VAF 40/531 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2
- GDPD4 | c.683G>A p.G228E | Missense Mutation (SNP) | VAF 42/306 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GLG1 | c.2144G>A p.G715E | Missense Mutation (SNP) | VAF 34/307 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GOLIM4 | c.1669C>T p.Q557* | Nonsense Mutation (SNP) | VAF 42/393 reads (11%) | called by muse, mutect2, varscan2
- GPR176 | c.1366G>A p.G456R | Missense Mutation (SNP) | VAF 59/478 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRB7 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 60/504 reads (12%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- HGFAC | c.910G>A p.G304S | Missense Mutation (SNP) | VAF 85/542 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HRH3 | c.607T>C p.S203P | Missense Mutation (SNP) | VAF 60/451 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- HSPB3 | c.312G>A p.M104I | Missense Mutation (SNP) | VAF 53/491 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IFT140 | c.3141G>A p.K1047= | Splice Region (SNP) | VAF 55/392 reads (14%) | called by muse, mutect2, varscan2
- IFT88 | c.632A>T p.N211I (on ENST00000319980 / NM_001318493.2; = p.N202I on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/290 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- IRS2 | c.1631C>T p.T544I | Missense Mutation (SNP) | VAF 76/638 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ITLN1 | c.687G>A p.R229= | Splice Region (SNP) | VAF 44/288 reads (15%) | called by muse, mutect2, varscan2
- KCNS2 | c.984_991del p.E328Dfs*21 | Frame Shift Del (DEL) | VAF 60/449 reads (13%) | called by mutect2, pindel, varscan2
- KITLG | c.89G>A p.R30K | Missense Mutation (SNP) | VAF 42/322 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KMO | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 42/314 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- KPNA4 | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 27/250 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KY | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 46/327 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- LARP4 | c.1487G>A p.G496D | Missense Mutation (SNP) | VAF 53/426 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- LGI3 | c.1325A>G p.Y442C | Missense Mutation (SNP) | VAF 63/505 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- LMTK3 | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 45/386 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- LNX1 | c.345G>T p.L115F | Missense Mutation (SNP) | VAF 41/353 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- LRIG2 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- LRIG3 | c.146C>T p.T49I | Missense Mutation (SNP) | VAF 60/551 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRC43 | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 30/288 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- MAGI2 | c.3326C>T p.P1109L | Missense Mutation (SNP) | VAF 69/516 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- MAPK8IP1 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 54/401 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- MBD5 | c.610G>A p.G204S | Missense Mutation (SNP) | VAF 44/446 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.49); called by muse, mutect2
- MGST2 | c.258_261dup p.Y88Hfs*16 | Frame Shift Ins (INS) | VAF 28/354 reads (8%) | called by mutect2, pindel
- MKX | c.737G>A p.R246K | Missense Mutation (SNP) | VAF 72/366 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MRPL37 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 57/449 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- MSGN1 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 68/493 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTMR11 | c.1647+1G>A p.X549_splice (on ENST00000439741 / NM_001145862.2; = p.X477_splice on NM_181873.3) | Splice Site (SNP) | VAF 35/266 reads (13%) | called by muse, mutect2, varscan2
- MUC5B | c.3012G>A p.W1004* | Nonsense Mutation (SNP) | VAF 52/477 reads (11%) | called by muse, mutect2, varscan2
- MYH14 | c.5273T>C p.L1758S | Missense Mutation (SNP) | VAF 45/428 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- MYO18B | c.3023G>A p.G1008E | Missense Mutation (SNP) | VAF 59/419 reads (14%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- MYRFL | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 36/324 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- NEURL1 | c.321G>T p.R107S | Missense Mutation (SNP) | VAF 41/221 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NLRP13 | c.2723G>A p.R908K | Missense Mutation (SNP) | VAF 43/405 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OBSCN | c.11497T>C p.W3833R | Missense Mutation (SNP) | VAF 66/453 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR52B4 | c.823C>T p.H275Y | Missense Mutation (SNP) | VAF 43/408 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- OR8K3 | c.295A>G p.T99A | Missense Mutation (SNP) | VAF 40/474 reads (8%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.011); called by muse, mutect2
- OXCT1 | c.734T>C p.V245A | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT tolerated (0.75); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PEG3 | c.1840C>T p.L614F | Missense Mutation (SNP) | VAF 53/467 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PGR | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 76/693 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PI4KA | c.3295G>A p.G1099R | Missense Mutation (SNP) | VAF 46/401 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLCH1 | c.3382C>T p.L1128F (on ENST00000340059 / NM_001130960.2; = p.L1120F on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/420 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLEKHM3 | c.2063A>G p.N688S | Missense Mutation (SNP) | VAF 46/384 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- PLEKHM3 | c.1921C>T p.H641Y | Missense Mutation (SNP) | VAF 41/438 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PRAM1 | c.1570G>A p.G524S | Missense Mutation (SNP) | VAF 46/329 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PRAMEF11 | c.345G>A p.W115* | Nonsense Mutation (SNP) | VAF 64/545 reads (12%) | called by muse, mutect2, varscan2
- PRKDC | c.10546C>T p.H3516Y | Missense Mutation (SNP) | VAF 61/456 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- PRKDC | c.8170G>A p.D2724N | Missense Mutation (SNP) | VAF 35/316 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRRT4 | c.1171C>T p.R391W | Missense Mutation (SNP) | VAF 87/590 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PTPRU | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 30/285 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PYGM | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 28/238 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RASGRP4 | c.730G>A p.V244I | Missense Mutation (SNP) | VAF 62/484 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- RGS6 | c.537-1G>A p.X179_splice | Splice Site (SNP) | VAF 35/176 reads (20%) | called by muse, mutect2, varscan2
- RNF169 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 67/431 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RP1 | c.1622A>T p.K541M | Missense Mutation (SNP) | VAF 44/338 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- RSPH14 | c.421G>A p.G141R | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- RYR1 | c.3850G>A p.E1284K | Missense Mutation (SNP) | VAF 68/553 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- SALL4 | c.1483C>T p.P495S | Missense Mutation (SNP) | VAF 68/388 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SAT1 | c.152T>C p.F51S | Missense Mutation (SNP) | VAF 75/436 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); called by muse, varscan2
- SCAF4 | c.2548C>T p.L850F | Missense Mutation (SNP) | VAF 43/376 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SCRN1 | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 39/387 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- SIRT3 | c.418G>A p.V140M | Missense Mutation (SNP) | VAF 58/478 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- SLC38A2 | c.674C>T p.S225F | Missense Mutation (SNP) | VAF 37/302 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC4A5 | c.1331G>T p.G444V | Missense Mutation (SNP) | VAF 92/612 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0); called by mutect2, varscan2
- SLITRK3 | c.1742G>A p.S581N | Missense Mutation (SNP) | VAF 35/448 reads (8%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.954); called by muse, mutect2
- SMC6 | c.1673C>A p.S558* | Nonsense Mutation (SNP) | VAF 52/381 reads (14%) | called by muse, mutect2, varscan2
- SPATA48 | c.749G>A p.W250* | Nonsense Mutation (SNP) | VAF 72/308 reads (23%) | called by muse, mutect2, varscan2
- SPEM2 | c.1481G>A p.R494K | Missense Mutation (SNP) | VAF 57/371 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- SSH2 | c.2029G>A p.E677K | Missense Mutation (SNP) | VAF 58/349 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- TAS2R14 | c.949T>A p.S317T | Missense Mutation (SNP) | VAF 25/251 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- TCERG1L | c.955C>T p.P319S | Missense Mutation (SNP) | VAF 44/307 reads (14%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCHHL1 | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 63/443 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TCTE1 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 87/598 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- TECPR1 | c.2029A>G p.T677A | Missense Mutation (SNP) | VAF 48/432 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TENM4 | c.2480G>A p.G827E | Missense Mutation (SNP) | VAF 45/384 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMCO5A | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 38/400 reads (10%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.916); called by muse, mutect2
- TRIM24 | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 54/650 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2
- TRIO | c.2519A>G p.N840S | Missense Mutation (SNP) | VAF 51/398 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TSSK1B | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 51/447 reads (11%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TTN | c.65912G>A p.G21971E (on ENST00000591111; = p.G14547E on NM_003319.4) | Missense Mutation (SNP) | VAF 56/546 reads (10%) | PolyPhen probably damaging (1); called by muse, mutect2
- UBAP2L | c.3032C>T p.S1011L | Missense Mutation (SNP) | VAF 50/408 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- UBR4 | c.11414G>A p.G3805E | Missense Mutation (SNP) | VAF 58/353 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- USP53 | c.2405C>T p.P802L | Missense Mutation (SNP) | VAF 33/320 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- VWA8 | c.2287G>A p.V763M | Missense Mutation (SNP) | VAF 25/293 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.103); called by muse, mutect2
- VWDE | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 38/416 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- WDFY3 | c.9263C>T p.P3088L | Missense Mutation (SNP) | VAF 50/475 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- WDR64 | c.1811G>A p.G604E | Missense Mutation (SNP) | VAF 42/399 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- XIRP1 | c.4172C>T p.P1391L | Missense Mutation (SNP) | VAF 21/489 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); called by muse, mutect2
- XIRP1 | c.4171C>T p.P1391S | Missense Mutation (SNP) | VAF 22/488 reads (5%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); called by muse, mutect2
- ZBTB21 | c.884C>T p.T295I | Missense Mutation (SNP) | VAF 37/343 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ZFAND1 | c.138G>A p.E46= | Splice Region (SNP) | VAF 31/251 reads (12%) | called by muse, mutect2, varscan2
- ZKSCAN4 | c.599G>A p.G200E | Missense Mutation (SNP) | VAF 38/353 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZMYND8 | c.1255G>A p.G419S (on ENST00000311275 / NM_001363741.2; = p.G439S on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/487 reads (16%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ZNF334 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 47/444 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF511-PRAP1 | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 57/302 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF71 | c.1261C>T p.Q421* | Nonsense Mutation (SNP) | VAF 95/638 reads (15%) | called by muse, mutect2, varscan2
- ZNF777 | c.1342G>A p.G448R | Missense Mutation (SNP) | VAF 22/267 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2
- ZNRF3 | c.1228C>T p.P410S (on ENST00000544604 / NM_001206998.2; = p.P310S on NM_032173.3) | Missense Mutation (SNP) | VAF 56/587 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.031); called by muse, mutect2
- ZRANB3 | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 70/575 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AACS | c.6C>T p.S2= | Silent (SNP) | VAF 34/272 reads (13%) | called by muse, varscan2
- ACP2 | c.1257G>A p.G419= | Silent (SNP) | VAF 52/450 reads (12%) | called by muse, mutect2, varscan2
- ADAM29 | c.867C>T p.F289= | Silent (SNP) | VAF 53/467 reads (11%) | called by muse, mutect2, varscan2
- ADCK1 | c.1125C>T p.P375= | Silent (SNP) | VAF 60/467 reads (13%) | catalogued as rs780209045; called by muse, mutect2, varscan2
- ANXA10 | c.327G>A p.E109= | Silent (SNP) | VAF 38/256 reads (15%) | catalogued as rs779510102; called by muse, mutect2, varscan2
- AP1G2 | c.1698G>A p.E566= | Silent (SNP) | VAF 52/323 reads (16%) | catalogued as rs761777964; called by muse, mutect2, varscan2
- BBS12 | c.1302C>T p.I434= | Silent (SNP) | VAF 60/505 reads (12%) | catalogued as rs773214415; ClinVar: likely benign; called by muse, mutect2
- BICRA | c.3906C>T p.A1302= | Silent (SNP) | VAF 56/564 reads (10%) | catalogued as rs777797255, COSV67606467; called by muse, mutect2, varscan2
- BMP7 | c.936C>T p.A312= | Silent (SNP) | VAF 41/377 reads (11%) | catalogued as COSV67783162; called by muse, mutect2, varscan2
- CALCOCO1 | c.1551G>A p.E517= | Silent (SNP) | VAF 41/299 reads (14%) | called by muse, mutect2, varscan2
- CCND1 | c.795C>T p.N265= | Silent (SNP) | VAF 79/567 reads (14%) | called by muse, varscan2
- CCNT2 | c.1158T>C p.S386= | Silent (SNP) | VAF 48/372 reads (13%) | catalogued as rs1460685292; called by muse, mutect2, varscan2
- CDK5RAP2 | c.5620C>T p.L1874= | Silent (SNP) | VAF 38/311 reads (12%) | called by muse, mutect2, varscan2
- CHRND | c.1155C>T p.S385= | Silent (SNP) | VAF 72/596 reads (12%) | called by muse, mutect2, varscan2
- CLIC5 | c.939C>T p.T313= (on ENST00000185206 / NM_001370649.1; = p.T154= on NM_016929.5) | Silent (SNP) | VAF 54/415 reads (13%) | called by muse, mutect2, varscan2
- COL1A1 | c.4062C>T p.F1354= | Silent (SNP) | VAF 55/412 reads (13%) | catalogued as rs377703930; called by muse, mutect2, varscan2
- COL21A1 | c.2505G>A p.P835= | Silent (SNP) | VAF 70/446 reads (16%) | catalogued as rs754347462; called by muse, mutect2, varscan2
- COL6A6 | c.5625C>T p.S1875= | Silent (SNP) | VAF 70/458 reads (15%) | catalogued as COSV100650152, COSV62017585, COSV62032547; called by muse, mutect2, varscan2
- CRAMP1 | c.3399C>T p.S1133= | Silent (SNP) | VAF 71/495 reads (14%) | catalogued as rs1303098804; called by muse, mutect2, varscan2
- CYP4X1 | c.162C>T p.F54= | Silent (SNP) | VAF 63/403 reads (16%) | catalogued as rs267598627, COSV64151218; called by muse, mutect2, varscan2
- DAPK2 | c.213C>T p.I71= | Silent (SNP) | VAF 46/401 reads (11%) | catalogued as rs375258891; called by muse, mutect2, varscan2
- DGKD | c.3390G>A p.K1130= (on ENST00000264057 / NM_152879.3; = p.K1086= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/310 reads (10%) | called by muse, mutect2, varscan2
- DNAJC17 | c.873C>T p.I291= | Silent (SNP) | VAF 56/398 reads (14%) | called by muse, mutect2, varscan2
- DYRK3 | c.1257C>T p.A419= | Silent (SNP) | VAF 61/456 reads (13%) | called by muse, mutect2, varscan2
- E2F7 | c.2670G>A p.R890= | Silent (SNP) | VAF 39/326 reads (12%) | called by muse, mutect2, varscan2
- EPHA3 | c.1341G>A p.R447= | Silent (SNP) | VAF 47/330 reads (14%) | catalogued as rs1166385630; called by muse, mutect2, varscan2
- FAM47B | c.435C>T p.L145= | Silent (SNP) | VAF 69/556 reads (12%) | catalogued as COSV100264251; called by muse, mutect2, varscan2
- FER1L5 | c.3801G>A p.T1267= (on ENST00000623019; = p.T1240= on NM_001293083.2) | Silent (SNP) | VAF 42/399 reads (11%) | catalogued as rs1421306160; called by muse, mutect2, varscan2
- FLT3LG | c.405C>T p.S135= | Silent (SNP) | VAF 62/507 reads (12%) | catalogued as rs749301992, COSV99201293; called by muse, mutect2, varscan2
- FLT4 | c.3297C>T p.S1099= | Silent (SNP) | VAF 43/416 reads (10%) | called by muse, mutect2, varscan2
- GALNT3 | c.1671G>A p.Q557= | Silent (SNP) | VAF 41/386 reads (11%) | called by muse, mutect2, varscan2
- GIMAP5 | c.303G>A p.G101= | Silent (SNP) | VAF 72/598 reads (12%) | catalogued as COSV57530070; called by muse, mutect2, varscan2
- GOT1L1 | c.481C>T p.L161= | Silent (SNP) | VAF 84/354 reads (24%) | catalogued as rs1298555085, COSV100294678; called by muse, mutect2, varscan2
- GPR89B | c.1239C>T p.V413= | Silent (SNP) | VAF 4/29 reads (14%) | called by mutect2, varscan2
- GRIP1 | c.2937G>A p.R979= (on ENST00000359742 / NM_001379345.1; = p.R927= on NM_021150.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 60/500 reads (12%) | called by muse, mutect2, varscan2
- GRM6 | c.1749C>T p.S583= | Silent (SNP) | VAF 76/564 reads (13%) | catalogued as rs747179681; called by muse, mutect2, varscan2
- GRPEL2 | c.423G>A p.E141= | Silent (SNP) | VAF 52/288 reads (18%) | catalogued as rs371081052; called by muse, mutect2, varscan2
- H3-5 | c.354C>T p.T118= | Silent (SNP) | VAF 71/477 reads (15%) | called by muse, mutect2, varscan2
- HINT1 | c.339C>T p.L113= | Silent (SNP) | VAF 31/393 reads (8%) | called by muse, mutect2
- HLA-DPA1 | c.732C>T p.I244= | Silent (SNP) | VAF 52/640 reads (8%) | called by muse, mutect2
- HNRNPL | c.1110C>T p.P370= | Silent (SNP) | VAF 60/355 reads (17%) | called by muse, mutect2, varscan2
- IL1R1 | c.1179G>A p.K393= | Silent (SNP) | VAF 52/433 reads (12%) | called by muse, mutect2, varscan2
- INTS1 | c.499C>T p.L167= | Silent (SNP) | VAF 37/579 reads (6%) | catalogued as COSV101247875; called by muse, mutect2
- KIF4B | c.3255C>T p.I1085= | Silent (SNP) | VAF 61/488 reads (13%) | catalogued as COSV70529006; called by muse, mutect2, varscan2
- KPNA7 | c.1377G>A p.G459= | Silent (SNP) | VAF 60/470 reads (13%) | called by muse, mutect2, varscan2
- KRTAP12-3 | c.267C>T p.S89= | Silent (SNP) | VAF 34/322 reads (11%) | catalogued as rs1275554472; called by muse, mutect2, varscan2
- LENG9 | c.1053G>A p.G351= | Silent (SNP) | VAF 80/547 reads (15%) | catalogued as COSV100002884; called by muse, mutect2, varscan2
- LGR6 | c.765C>T p.T255= (on ENST00000367278 / NM_001017403.1; = p.T203= on NM_021636.3) | Silent (SNP) | VAF 41/320 reads (13%) | called by muse, mutect2, varscan2
- LYSMD1 | c.225C>T p.S75= | Silent (SNP) | VAF 35/325 reads (11%) | catalogued as rs1312079951; called by muse, mutect2, varscan2
- MAPK8IP1 | c.567G>A p.Q189= | Silent (SNP) | VAF 54/399 reads (14%) | called by muse, mutect2, varscan2
- MTMR8 | c.1188C>T p.S396= | Silent (SNP) | VAF 56/319 reads (18%) | catalogued as rs1386078818; called by muse, mutect2, varscan2
- MXRA5 | c.4107C>T p.S1369= | Silent (SNP) | VAF 65/450 reads (14%) | called by muse, mutect2, varscan2
- NEB | c.6018C>T p.I2006= | Silent (SNP) | VAF 55/409 reads (13%) | called by muse, mutect2, varscan2
- NLRP14 | c.783C>T p.F261= | Silent (SNP) | VAF 37/340 reads (11%) | catalogued as rs776087967, COSV55063932; called by muse, mutect2, varscan2
- NSUN4 | c.42G>A p.K14= | Silent (SNP) | VAF 59/390 reads (15%) | catalogued as rs780949358; called by muse, mutect2, varscan2
- NYAP1 | c.105G>A p.G35= | Silent (SNP) | VAF 74/567 reads (13%) | catalogued as rs1156361546; called by muse, mutect2, varscan2
- OCA2 | c.507C>T p.S169= | Silent (SNP) | VAF 42/357 reads (12%) | called by muse, mutect2, varscan2
- OCIAD1 | c.651G>A p.K217= | Silent (SNP) | VAF 37/316 reads (12%) | called by muse, mutect2, varscan2
- OR4A5 | c.121C>T p.L41= | Silent (SNP) | VAF 62/430 reads (14%) | called by muse, mutect2, varscan2
- OR52E1 | c.486C>T p.I162= | Silent (SNP) | VAF 38/328 reads (12%) | catalogued as rs948588850; called by muse, mutect2, varscan2
- OR5AS1 | c.312C>T p.F104= | Silent (SNP) | VAF 48/439 reads (11%) | catalogued as rs142110904; called by muse, mutect2, varscan2
- OR5D14 | c.606C>T p.F202= | Silent (SNP) | VAF 45/394 reads (11%) | catalogued as rs866261956; called by muse, mutect2, varscan2
- P4HA1 | c.735A>G p.L245= | Silent (SNP) | VAF 38/213 reads (18%) | called by muse, mutect2, varscan2
- PAK3 | c.1176C>T p.F392= (on ENST00000262836 / NM_001324328.2; = p.F377= on NM_002578.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 42/322 reads (13%) | catalogued as COSV53276029; called by muse, mutect2, varscan2
- PAPPA2 | c.3321C>T p.N1107= | Silent (SNP) | VAF 38/300 reads (13%) | called by muse, mutect2, varscan2
- PCDH15 | c.5232C>T p.A1744= | Silent (SNP) | VAF 50/528 reads (9%) | catalogued as rs752000225; called by muse, mutect2
- PDIA4 | c.1317C>T p.V439= (on ENST00000286091 / NM_001371244.1; = p.V438= on NM_004911.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 55/327 reads (17%) | called by muse, mutect2, varscan2
- PEG10 | c.669C>A p.V223= (on ENST00000482108 / NM_001040152.2; = p.V257= on NM_015068.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 64/511 reads (13%) | catalogued as COSV71787950; called by muse, mutect2, varscan2
- PGF | c.663G>A p.R221= (on ENST00000405431; = p.R170= on NM_002632.5) | Silent (SNP) | VAF 56/337 reads (17%) | called by muse, mutect2, varscan2
- PLA2G4F | c.1239G>A p.V413= | Silent (SNP) | VAF 42/369 reads (11%) | called by muse, mutect2, varscan2
- PLCB2 | c.2544G>A p.A848= | Silent (SNP) | VAF 55/370 reads (15%) | catalogued as rs762999371; called by muse, mutect2, varscan2
- PLK1 | c.261T>G p.S87= | Silent (SNP) | VAF 53/456 reads (12%) | called by muse, mutect2, varscan2
- PLK1 | c.262C>T p.L88= | Silent (SNP) | VAF 53/451 reads (12%) | called by muse, mutect2, varscan2
- POLR3GL | c.417G>A p.K139= | Silent (SNP) | VAF 48/330 reads (15%) | catalogued as rs139764011; called by muse, mutect2, varscan2
- POMGNT1 | c.558G>A p.K186= | Silent (SNP) | VAF 58/421 reads (14%) | called by muse, mutect2, varscan2
- POTEB3 | c.474C>T p.I158= | Silent (SNP) | VAF 14/528 reads (3%) | called by muse, mutect2
- PPP1R15A | c.138G>A p.L46= | Silent (SNP) | VAF 72/483 reads (15%) | called by muse, mutect2, varscan2
- PRDM16 | c.2556G>A p.P852= | Silent (SNP) | VAF 80/633 reads (13%) | catalogued as rs570631594; ClinVar: likely benign; called by muse, mutect2, varscan2
- RAG1 | c.1318C>T p.L440= | Silent (SNP) | VAF 62/510 reads (12%) | called by muse, mutect2, varscan2
- RFK | c.222G>A p.T74= | Silent (SNP) | VAF 35/292 reads (12%) | catalogued as rs767893968, COSV65060969; called by muse, mutect2, varscan2
- RNF213 | c.12762G>A p.K4254= | Silent (SNP) | VAF 43/276 reads (16%) | catalogued as COSV100301198; called by muse, mutect2, varscan2
- RNF225 | c.198C>T p.I66= | Silent (SNP) | VAF 92/622 reads (15%) | called by muse, varscan2
- SACM1L | c.1611C>T p.I537= | Silent (SNP) | VAF 55/378 reads (15%) | called by muse, mutect2
- SEPTIN6 | c.999G>A p.G333= | Silent (SNP) | VAF 40/322 reads (12%) | called by muse, mutect2, varscan2
- SIGLEC11 | c.552G>A p.K184= | Silent (SNP) | VAF 30/464 reads (6%) | called by muse, mutect2
- SLC1A7 | c.441C>T p.F147= | Silent (SNP) | VAF 41/446 reads (9%) | catalogued as rs763622640; called by muse, mutect2
- SLC38A2 | c.960C>T p.S320= | Silent (SNP) | VAF 37/275 reads (13%) | catalogued as COSV56745813; called by muse, mutect2, varscan2
- SLCO1C1 | c.573C>T p.F191= | Silent (SNP) | VAF 62/424 reads (15%) | catalogued as COSV56871785, COSV56879186; called by muse, mutect2, varscan2
- SPAST | c.1590C>T p.T530= | Silent (SNP) | VAF 40/303 reads (13%) | called by muse, mutect2, varscan2
- STAT5A | c.894C>T p.H298= | Silent (SNP) | VAF 32/386 reads (8%) | called by muse, mutect2, varscan2
- STC2 | c.249G>A p.G83= | Silent (SNP) | VAF 39/369 reads (11%) | catalogued as rs753936878, COSV54181030; called by muse, mutect2, varscan2
- STRN | c.1476A>G p.L492= | Silent (SNP) | VAF 40/272 reads (15%) | called by mutect2, varscan2
- TFF1 | c.54G>A p.L18= | Silent (SNP) | VAF 38/422 reads (9%) | called by muse, mutect2
- TLR3 | c.1671C>T p.F557= | Silent (SNP) | VAF 45/360 reads (13%) | catalogued as COSV57167645; called by muse, mutect2, varscan2
- TMEM185B | c.588C>T p.F196= | Silent (SNP) | VAF 60/606 reads (10%) | called by muse, mutect2
- TTN | c.77403C>T p.F25801= (on ENST00000591111; = p.F18377= on NM_003319.4) | Silent (SNP) | VAF 50/431 reads (12%) | called by muse, mutect2, varscan2
- TTN | c.22536G>A p.L7512= (on ENST00000591111; = p.L6585= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 52/426 reads (12%) | catalogued as rs1255955033, COSV60299915; called by muse, mutect2, varscan2
- UGT3A2 | c.384G>A p.K128= | Silent (SNP) | VAF 35/310 reads (11%) | called by muse, mutect2, varscan2
- URB1 | c.3975C>T p.I1325= | Silent (SNP) | VAF 56/459 reads (12%) | called by muse, mutect2, varscan2
- VSIG10L | c.2154G>A p.R718= | Silent (SNP) | VAF 67/594 reads (11%) | catalogued as rs1395501925; called by muse, mutect2, varscan2
- WDR87 | c.4209G>A p.G1403= | Silent (SNP) | VAF 51/407 reads (13%) | catalogued as COSV58202867; called by muse, mutect2, varscan2
- YPEL1 | c.21C>T p.S7= | Silent (SNP) | VAF 34/338 reads (10%) | called by muse, mutect2
- ZFHX3 | c.399C>T p.I133= | Silent (SNP) | VAF 70/532 reads (13%) | catalogued as rs368497120; called by muse, varscan2
- ZNF135 | c.912G>A p.G304= (on ENST00000313434 / NM_001289401.2; = p.G316= on NM_003436.4) | Silent (SNP) | VAF 65/484 reads (13%) | catalogued as COSV100536658; called by muse, mutect2, varscan2
- ZNF628 | c.2307G>A p.Q769= | Silent (SNP) | VAF 94/719 reads (13%) | called by muse, mutect2, varscan2
- ZNF638 | c.3864C>T p.P1288= | Silent (SNP) | VAF 35/311 reads (11%) | catalogued as rs1213308503; called by muse, mutect2, varscan2
- ZNF646 | c.1602G>A p.K534= | Silent (SNP) | VAF 63/530 reads (12%) | called by muse, mutect2, varscan2
- ZNF883 | c.84G>A p.L28= | Silent (SNP) | VAF 53/346 reads (15%) | called by muse, mutect2, varscan2
- ZNRF3 | c.1866G>A p.L622= (on ENST00000544604 / NM_001206998.2; = p.L522= on NM_032173.3) | Silent (SNP) | VAF 61/710 reads (9%) | catalogued as rs374486157; called by muse, mutect2
- ZP2 | c.174G>A p.R58= | Silent (SNP) | VAF 53/372 reads (14%) | called by muse, mutect2, varscan2
- ABL2 | c.1652-386C>T | Intron (SNP) | VAF 40/412 reads (10%) | called by muse, mutect2
- AGAP3 | c.224-1745G>A | Intron (SNP) | VAF 21/329 reads (6%) | called by muse, mutect2
- AL353804.6 | chrX:73827103 C>T | 3'Flank (SNP) | VAF 57/300 reads (19%) | called by muse, mutect2, varscan2
- ALMS1P1 | chr2:73700928 G>A | 3'Flank (SNP) | VAF 72/549 reads (13%) | catalogued as rs773358217; called by muse, mutect2
- ARHGEF4 | chr2:130914756 G>A | 5'Flank (SNP) | VAF 30/329 reads (9%) | called by muse, mutect2
- ATP13A2 | c.*126C>T | 3'UTR (SNP) | VAF 100/632 reads (16%) | catalogued as rs753524964; called by muse, mutect2, varscan2
- C6orf62 | chr6:24719887 C>T | 5'Flank (SNP) | VAF 35/250 reads (14%) | called by muse, mutect2, varscan2
- DCHS2 | n.5526G>A | RNA (SNP) | VAF 39/364 reads (11%) | called by muse, mutect2, varscan2
- KCTD1 | c.-15-47100G>A | Intron (SNP) | VAF 52/373 reads (14%) | called by muse, varscan2
- NBPF25P | n.956G>T | RNA (SNP) | VAF 40/448 reads (9%) | called by muse, mutect2
- PDE1A | c.101+95669G>A | Intron (SNP) | VAF 36/400 reads (9%) | called by muse, mutect2
- PHYHIPL | c.*1026G>A | 3'UTR (SNP) | VAF 36/222 reads (16%) | called by muse, mutect2, varscan2
- SPATA13 | c.-222-25581C>T | Intron (SNP) | VAF 63/421 reads (15%) | called by muse, mutect2, varscan2
- ST18 | c.*2130T>C | 3'UTR (SNP) | VAF 25/190 reads (13%) | called by muse, mutect2, varscan2
- TTN | c.10360+4345A>G | Intron (SNP) | VAF 39/305 reads (13%) | catalogued as rs1348914862; called by muse, mutect2, varscan2
- ZFYVE9 | c.*130G>A | 3'UTR (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- ZNF578 | chr19:52451362 C>T | 5'Flank (SNP) | VAF 37/421 reads (9%) | catalogued as COSV99989789; called by muse, mutect2
